Surgical pathology report (de-identified scan), TCGA case TCGA-NP-A5B3, project TCGA-KICH (Kidney Chromophobe), tissue source site International Genomics Consortium, specimen TCGA-NP-A5B3-01A (Primary Tumor).

[page 1 of 2]
Carcinoma, renal cell, chromophobe type
831713

Site: *Ⓡ* Kidney NOS C64.9

12/24/12 *JA*

MRN: [REDACTED]

Age: [REDACTED] Sex: M

DOB: [REDACTED]

Surgical Pathology

Histopathological Examination

Path#: [REDACTED]

Pre-Op Diagnosis : Right Renal Mass
Order Physician : [REDACTED]
Specimens : Kidney, right for
Frozen Diagnosis :

Report : GROSS EXAMINATION:

The specimen is received fresh labeled with the name of the patient and labeled as kidney, right. The specimen consists of a kidney and attached perinephric fat. The kidney measures 11.5 x 6 x 4.5 cm and weighs 201 grams. The ureter and vascular margins are submitted in block 1. The renal sinus/hilar margin is submitted in block 2. Sectioning into the kidney shows two masses. The first is in the mid-posterior aspect. This mass is brown and measures 3.8 cm in greatest dimension. It bulges against the capsule, but the capsule strips with ease from over the mass. Sections of the capsule overlying the mass are submitted in block 3. The mass does not grossly involve the renal sinus. A section of the mass and renal sinus is submitted in block 4. Additional sections of the mass are submitted in blocks 5-8. The second mass is in the mid-lateral aspect of the kidney and is 0.6 cm away from the first mass, measuring 1.0 x 0.8 x 0.8 cm. The mass bulges against the capsule, but the capsule strips with ease. Sections of the capsule overlying the mass are submitted in block 9. The capsule does not grossly involve the renal sinus. A section of the two masses and intervening normal-appearing tissue is submitted in block 10. Sections of the second mass are submitted in blocks 11-13. The pelves and calices are not grossly dilated. The cortex averages 0.8 cm. A random section of kidney is submitted in block 14. The attached fat is dissected, and no lymph nodes or adrenal tissue are identified. [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

Kidney, right nephrectomy:

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Path #: [REDACTED]
Visit #: [REDACTED]

Page 1 of 2

[page 2 of 2]
- Chromophobe renal cell carcinoma, two foci, 3.8 and 1.0 cm, see cancer case summary checklist.
- Tumor limited to kidney.
- Margins free of tumor.
- [T-71000 M-82703 189.0 P3-44070]

KIDNEY: Nephrectomy, Partial or Radical

PROCEDURE: Radial nephrectomy.
SPECIMEN LATERALITY: Right.
TUMOR SITE: Middle.
TUMOR SIZE: 3.8 cm, 1.0 cm
TUMOR FOCALITY: Multifocal.
MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney.

HISTOLOGIC TYPE: Chromophobe renal cell carcinoma.
SARCOMATOID FEATURES: Not identified.
TUMOR NECROSIS: Not identified.
HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): G2, nuclei slightly irregular approximately 15 mm (nucleoli evident).
MICROSCOPIC TUMOR EXTENSION: Tumor limited to kidney.

MARGINS: Uninvolved by invasive carcinoma.

LYMPH-VASCULAR INVASION: Not identified.

PATHOLOGIC STAGING (pTNM):
TNM Descriptors: N/A
Primary Tumor (pT): pT1a: Tumor 4 cm or less in greatest dimension, limited to kidney.
Regional Lymph Nodes (pN): pNX: Cannot be assessed.
Distant Metastasis (pM): N/A

PATHOLOGIC FINDINGS IN NONNEOPLASTIC KIDNEY: None identified.

COMMENT:
The case has been delayed for immunohistochemical studies. have been performed. as the differential would include an oncocytoma versus chromophobe renal cell carcinoma versus granular variant of clear cell type renal cell carcinoma. Stains support the diagnosis (Positive stains: Cytokeratin 7, EMA, CD117, E-Cadherin, CD10; Negative stains: Vimintin, Cytokeratin 20). Control slides were reviewed and found appropriate.

SUMMARY OF PATHOLOGIC STAGING: pT1aNX

Intradepartmental consultation obtained.

[REDACTED]

[REDACTED]

Case is Circled	☒	☐
Reviewed	☒	☐

lw 1/24/13

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Path #: [REDACTED]
Visit #: [REDACTED]

Source: NCI Genomic Data Commons file 9631d2cf-6c43-49c3-b9c6-e693f810b520 (TCGA-NP-A5B3.97F17D1B-5EBF-4940-88D5-8ADF8E71ECCF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).